Somatic mutation profile of tumor specimen TCGA-DU-5854-01A (aliquot TCGA-DU-5854-01A-11D-1705-08) from TCGA case TCGA-DU-5854, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 57.8 years (21,106 days).
Specimen TCGA-DU-5854-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff474d99-8c59-4869-8953-186040bba505.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-5854-10A (Blood Derived Normal), aliquot TCGA-DU-5854-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce726e4d-417e-4d1f-8adf-e2e5dce9c971

The open-access MAF lists 43 somatic variants for this specimen: 35 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 30, Silent 8, Nonsense Mutation 2, Frame Shift Del 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGA | c.233G>A p.S78N | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.527); catalogued as COSV52807767; called by muse, mutect2, varscan2
- C1orf158 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs750241731, COSV55346815, COSV55347143, COSV99847419; called by muse, mutect2, varscan2
- CEP128 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200105295, COSV53672384; called by muse, mutect2, varscan2
- CFAP65 | c.5237C>T p.P1746L | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs766938631, COSV58558638; called by muse, mutect2, varscan2
- EDN2 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779091830, COSV65423701; called by muse, mutect2, varscan2
- FAM83B | c.322T>C p.W108R | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV60927504; called by muse, mutect2, varscan2
- HEATR1 | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV63979599; called by muse, mutect2, varscan2
- LIG4 | c.44C>G p.P15R | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV63598235; called by muse, mutect2, varscan2
- MORN3 | c.541G>A p.G181S | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782296653, COSV62507889; called by muse, mutect2, varscan2
- MTCP1 | c.263A>G p.Q88R | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV62900820; called by muse, mutect2, varscan2
- MUC16 | c.35279C>A p.T11760N | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.743); catalogued as COSV67498149; called by muse, mutect2, varscan2
- MUC16 | c.1140C>A p.H380Q | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.136); catalogued as rs758250847, COSV67498155; called by muse, mutect2, varscan2
- MXRA5 | c.8002C>T p.R2668C | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs771549368, COSV54252707; called by muse, mutect2, varscan2
- NRG1 | c.1580C>T p.T527M (on ENST00000405005 / NM_013964.5; = p.T532M on NM_013956.5) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1320798326, COSV55149267; called by muse, mutect2, varscan2
- OR2L8 | c.422T>A p.V141E | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); catalogued as COSV61728624; called by muse, mutect2, varscan2
- OR4C6 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.066); catalogued as rs146965889, COSV100051763; called by muse, mutect2, varscan2
- PLXNA4 | c.3967C>T p.R1323W | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747801776, COSV58104969; called by muse, mutect2, varscan2
- PPP1R17 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs367827815; called by muse, mutect2, varscan2
- RECK | c.1431C>A p.Y477* | Nonsense Mutation (SNP) | VAF 10/68 reads (15%) | catalogued as COSV65036481; called by muse, mutect2, varscan2
- RFX6 | c.2261C>T p.P754L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.084); catalogued as rs563217936, COSV60587389; called by muse, mutect2, varscan2
- RNF130 | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs762039749, COSV56154308; called by muse, mutect2
- RNF32 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58731593; called by muse, mutect2, varscan2
- SAGE1 | c.2654C>T p.A885V | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782694777, COSV61014780; called by muse, mutect2, varscan2
- SLC45A3 | c.1376C>T p.A459V | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs140263007; called by muse, mutect2, varscan2
- SNX7 | c.589A>G p.T197A | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as COSV60272462; called by muse, mutect2, varscan2
- TMEM132B | c.3184G>A p.G1062R | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54772455; called by muse, mutect2, varscan2
- TMEM252 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs566744205, COSV66065360; called by muse, mutect2, varscan2
- ZNF518B | c.2066G>A p.R689H | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.791); catalogued as rs767222420, COSV58725071; called by muse, mutect2, varscan2
- ZNF804B | c.3338A>G p.N1113S | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.03); catalogued as rs748457652, COSV60858421; called by muse, mutect2, varscan2
- ADPRS | c.524_543delinsAG p.R175_T181delinsQ | In Frame Del (DEL) | VAF 14/54 reads (26%) | called by pindel, varscan2*
- IGHV1-58 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- MECOM | c.1845del p.S615Rfs*29 (on ENST00000468789 / NM_001105078.4; = p.S803Rfs*29 on NM_004991.4) | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | called by mutect2, pindel, varscan2
- MTM1 | c.1474A>G p.T492A | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- SPX | c.305del p.N102Tfs*23 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | called by pindel, varscan2
- STT3B | c.857dup p.Y286* | Nonsense Mutation (INS) | VAF 7/33 reads (21%) | called by mutect2, pindel, varscan2
- HDX | c.288T>G p.S96= | Silent (SNP) | VAF 39/132 reads (30%) | catalogued as COSV52983392; called by muse, mutect2, varscan2
- OR10J3 | c.972G>A p.A324= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as rs201786076, COSV100171731; called by muse, mutect2, varscan2
- PDGFRA | c.1419C>T p.I473= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as COSV57275096; called by muse, mutect2, varscan2
- PNMA5 | c.180C>T p.D60= | Silent (SNP) | VAF 45/154 reads (29%) | catalogued as rs1248735939, COSV62626385; called by muse, mutect2, varscan2
- RADX | c.60G>A p.P20= | Silent (SNP) | VAF 29/121 reads (24%) | catalogued as rs1416898545, COSV65318358, COSV65320264; called by muse, mutect2, varscan2
- RRAS2 | c.501T>G p.A167= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV56332655; called by muse, mutect2, varscan2
- TRIM69 | c.621T>C p.F207= (on ENST00000329464 / NM_182985.5; = p.F48= on NM_080745.5) | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV57805560; called by muse, mutect2, varscan2
- TRPV6 | c.1236A>G p.L412= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV63893987; called by muse, mutect2, varscan2
